Somatic mutation profile of tumor specimen BLGSP-71-19-00111-01A (aliquot BLGSP-71-19-00111-01A-01D-A634-33) from CGCI case BLGSP-71-19-00111, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 5.1 years (1,849 days).
Specimen BLGSP-71-19-00111-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 20edf88c-412d-4c0f-8584-a5ba6f40c874.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BLGSP-71-19-00111-10A (Blood Derived Normal), aliquot BLGSP-71-19-00111-10A-01D-A634-33; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24c2a32c-16f4-4e77-9e21-3149aa76c42f

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, 5'Flank 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCR | c.649C>T p.H217Y | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as rs747544800, COSV59932966; called by muse, mutect2, varscan2
- GNA13 | c.1121T>A p.L374H | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71474931, COSV71474932; called by muse, mutect2
- GNA13 | c.561+2T>G p.X187_splice | Splice Site (SNP) | VAF 19/364 reads (5%) | catalogued as COSV71474439, COSV71474967, COSV71475447; called by muse, mutect2
- GNA13 | c.111C>G p.C37W | Missense Mutation (SNP) | VAF 93/218 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.87); catalogued as COSV71475348; called by muse, mutect2, varscan2
- ID3 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1055074154, COSV65800845, COSV65801501; called by muse, mutect2, varscan2
- LRP1B | c.2039G>C p.W680S | Missense Mutation (SNP) | VAF 17/545 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67261770; called by muse, mutect2
- DDX3X | c.1379T>C p.L460S (on ENST00000399959; = p.L461S on NM_001356.5) | Missense Mutation (SNP) | VAF 354/385 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RFX7 | c.2023_2024del p.K675Vfs*6 (on ENST00000559447 / NM_001368074.1; = p.K772Vfs*6 on NM_022841.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 355/863 reads (41%) | called by mutect2, pindel, varscan2
- MIR1204 | chr8:127795459 C>T | 5'Flank (SNP) | VAF 297/665 reads (45%) | catalogued as rs1426150643; called by muse, mutect2, varscan2
